Somatic mutation profile of tumor specimen TCGA-AB-2914-03A (aliquot TCGA-AB-2914-03A-01W-0732-08) from TCGA case TCGA-AB-2914, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 22.7 years (8,280 days).
Specimen TCGA-AB-2914-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 065d255c-cf4a-4058-81c3-357a0a575e1e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2914-11A (Solid Tissue Normal), aliquot TCGA-AB-2914-11A-01W-0732-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/01a7d4e5-584f-4994-b15b-c58a06ca9c72

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Silent 1, In Frame Del 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CBL | c.1096-1G>C p.X366_splice | Splice Site (SNP) | VAF 6/19 reads (32%) | catalogued as rs397517076, CD1314297, CS099550, CS150637, COSV50631547, COSV50635311, COSV50641081; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS18 | c.2498C>T p.A833V | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs147816593; called by muse, mutect2, varscan2
- HTR3E | c.1240G>A p.E414K (on ENST00000415389 / NM_001256613.1; = p.E429K on NM_182589.2) | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.061); catalogued as rs1279651817, COSV100094137; called by muse, mutect2
- ISLR | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.076); catalogued as rs543753338, COSV51433786; called by muse, mutect2, varscan2
- PLPPR4 | c.2095G>A p.G699R | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as rs1335555385, COSV64565728; called by mutect2, varscan2
- STRN | c.1213_1215del p.S405del | In Frame Del (DEL) | VAF 51/434 reads (12%) | catalogued as rs755625860; called by pindel, varscan2
- ZFHX4 | c.1598C>A p.T533K | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV99262898; called by mutect2, varscan2
- KANSL1 | c.895dup p.R299Pfs*16 | Frame Shift Ins (INS) | VAF 24/75 reads (32%) | called by mutect2, pindel, varscan2
- PNPLA5 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 2/24 reads (8%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2
- H3-4 | c.264G>A p.S88= | Silent (SNP) | VAF 25/196 reads (13%) | catalogued as COSV64210626; called by muse, mutect2, varscan2
